Somatic mutation profile of tumor specimen ALCH-B24Y-TTP1-A (aliquot ALCH-B24Y-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B24Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.7 years (25,093 days).
Specimen ALCH-B24Y-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 587ef916-fe3c-4429-809f-8b3a596b1298.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B24Y-NB1-A (Blood Derived Normal), aliquot ALCH-B24Y-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57db375c-bde8-49a5-a7e6-574dc212849f

The open-access MAF lists 113 somatic variants for this specimen: 85 protein-altering or splice-affecting, 17 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 17, Nonsense Mutation 11, Intron 4, 5'UTR 3, RNA 3, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/447 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.1417T>A p.C473S | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100900409; called by muse, mutect2
- ALDH1L1 | c.410C>A p.A137E | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1158482557, COSV56413602; called by muse, mutect2, varscan2
- APLF | c.1231G>T p.G411C | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58146951; called by muse, mutect2
- BRINP1 | c.200C>A p.T67N | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1487814800; called by muse, mutect2, varscan2
- BRINP3 | c.1724C>A p.P575H | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750809290, COSV66521343, COSV66523532; called by muse, mutect2
- CPSF1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs782249962; called by muse, mutect2
- DRAM2 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 21/373 reads (6%) | catalogued as COSV54414747; called by muse, mutect2
- EDNRB | c.1295G>T p.S432I (on ENST00000377211 / NM_001201397.1; = p.S342I on NM_000115.5) | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.572); catalogued as CM101985; called by muse, mutect2
- ESAM | c.402A>C p.Q134H | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.667); catalogued as COSV99631630; called by muse, mutect2
- FSTL5 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 19/278 reads (7%) | catalogued as rs1015969618; called by muse, mutect2
- GRIA2 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.314); catalogued as COSV99643069; called by muse, mutect2
- GZMH | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53539020; called by muse, mutect2
- LCOR | c.2710G>C p.G904R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.787); catalogued as rs568325585; called by muse, mutect2, varscan2
- MGA | c.2848C>T p.Q950* | Nonsense Mutation (SNP) | VAF 7/129 reads (5%) | catalogued as COSV54949413; called by muse, mutect2
- NR5A1 | c.250C>G p.R84G | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM073247, COSV101007711; called by muse, mutect2
- PURB | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67480205; called by muse, mutect2, varscan2
- RSPO2 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52655047; called by muse, mutect2, varscan2
- SART3 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs371173853; called by muse, mutect2
- SATL1 | c.620C>T p.P207L (on ENST00000395409; = p.P394L on NM_001012980.2) | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.655); catalogued as COSV100261129; called by muse, mutect2
- SDK2 | c.2753C>A p.P918Q | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66187107; called by muse, mutect2, varscan2
- SPHKAP | c.4560G>A p.W1520* | Nonsense Mutation (SNP) | VAF 14/209 reads (7%) | catalogued as rs868281628, COSV60883262; called by muse, mutect2
- SRRM4 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1363535954, COSV57425075; called by muse, mutect2
- TENT5B | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.85); catalogued as rs1270583219, COSV100006566; called by muse, mutect2
- TPO | c.2487C>A p.Y829* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | catalogued as COSV100221133; called by muse, mutect2
- TRHR | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 46/528 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs150719639; called by muse, mutect2
- ZNF248 | c.1628C>T p.T543I | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1001125623; called by muse, mutect2
- ZNF701 | c.848G>T p.R283L (on ENST00000301093; = p.R217L on NM_018260.3) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs750484328, COSV56525644; called by muse, mutect2, varscan2
- ABCA2 | c.4071G>T p.Q1357H (on ENST00000614293; = p.Q1327H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ACADSB | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- ADAM12 | c.2705C>A p.S902Y | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); called by muse, mutect2
- ADAMTS16 | c.306A>T p.K102N | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- AGAP9 | c.1870G>T p.G624C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- AK7 | c.1666G>T p.A556S | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.01); called by muse, mutect2
- APOB | c.7210C>A p.L2404I | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.193); called by muse, mutect2
- ATXN2 | c.2839T>C p.S947P (on ENST00000550104; = p.S787P on NM_002973.4) | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); called by muse, mutect2
- CCDC91 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- CDH12 | c.1542C>A p.D514E | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CFAP47 | c.8779C>A p.L2927I | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.073); called by muse, mutect2
- CHRM2 | c.201T>A p.C67* | Nonsense Mutation (SNP) | VAF 40/557 reads (7%) | called by muse, mutect2
- COL1A2 | c.2998-2A>T p.X1000_splice | Splice Site (SNP) | VAF 26/374 reads (7%) | called by muse, mutect2
- COL5A3 | c.4595G>A p.R1532H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- DNASE2B | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EXD3 | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EYS | c.1828G>C p.G610R | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.038); called by muse, mutect2
- F5 | c.899T>G p.V300G | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2
- FAT3 | c.218T>C p.I73T | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- FBP2 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRID2 | c.1455C>A p.N485K | Missense Mutation (SNP) | VAF 22/460 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HHAT | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.216); called by muse, mutect2
- HMCN1 | c.3805C>A p.P1269T | Missense Mutation (SNP) | VAF 17/417 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- HNF4A | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2
- KANSL3 | c.710C>G p.T237S | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2
- KIAA1217 | c.2593A>T p.S865C | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- LAMB3 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LTBP1 | c.1627G>T p.V543F (on ENST00000404816 / NM_206943.4; = p.V217F on NM_000627.4) | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- MAGEC2 | c.1055A>T p.D352V | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, varscan2
- MYO16 | c.4153C>A p.R1385S | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- NLRP12 | c.2689G>T p.G897W | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NWD2 | c.2924C>A p.P975H | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR52E4 | c.296G>C p.C99S | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR6Q1 | c.797C>A p.T266N | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2
- PIAS4 | c.533A>T p.N178I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PKHD1 | c.10422G>A p.M3474I | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLEKHA5 | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2
- RASA3 | c.625A>T p.S209C | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); called by muse, mutect2
- RFPL1 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPSA | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 20/364 reads (5%) | called by muse, mutect2
- SCG2 | c.441G>C p.M147I | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2
- SCN3A | c.2306G>T p.C769F | Missense Mutation (SNP) | VAF 18/343 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SI | c.3193G>C p.V1065L | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); called by muse, mutect2
- SLC12A6 | c.1655G>T p.G552V (on ENST00000354181 / NM_001365088.1; = p.G501V on NM_005135.2) | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- SLC17A7 | c.954C>G p.F318L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SMG1 | c.2614G>C p.G872R | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPTB | c.6762C>A p.H2254Q | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2
- TENM4 | c.6203T>C p.I2068T | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); called by muse, mutect2
- TMX4 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- TPO | c.2743G>T p.E915* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | called by mutect2, varscan2
- TRAV1-2 | c.156C>A p.Y52* | Nonsense Mutation (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- TRPM7 | c.4499G>T p.S1500I | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.054); called by muse, mutect2
- TTN | c.5560G>T p.E1854* (on ENST00000591111; = p.E1808* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 13/303 reads (4%) | called by muse, mutect2
- UBAP2L | c.1393C>G p.Q465E | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.9); called by muse, mutect2
- USP34 | c.3854G>T p.G1285V | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- ZNF248 | c.1630G>T p.G544W | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF831 | c.4571T>A p.L1524Q | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2
- ALG13 | c.2397T>A p.R799= | Silent (SNP) | VAF 15/214 reads (7%) | called by muse, mutect2
- CCDC18 | c.408C>A p.S136= | Silent (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- DACT1 | c.2151C>T p.Y717= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as rs760763089, COSV60022557; called by muse, mutect2
- DNHD1 | c.8880G>A p.L2960= | Silent (SNP) | VAF 19/236 reads (8%) | called by muse, mutect2
- FPGT-TNNI3K | c.426A>T p.I142= | Silent (SNP) | VAF 18/270 reads (7%) | catalogued as COSV58547813; called by muse, mutect2
- GBP7 | c.225C>A p.T75= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- HDAC9 | c.120T>A p.V40= | Silent (SNP) | VAF 16/339 reads (5%) | called by muse, mutect2
- LILRB2 | c.1410C>A p.V470= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV58746263; called by muse, mutect2
- NAV3 | c.3567G>C p.S1189= | Silent (SNP) | VAF 14/236 reads (6%) | catalogued as rs759382547, COSV57069101, COSV57109340; called by muse, mutect2
- OGDHL | c.2607G>T p.R869= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs1478796664; called by muse, mutect2
- OR13A1 | c.954C>A p.A318= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- OR2T35 | c.915A>T p.L305= | Silent (SNP) | VAF 14/171 reads (8%) | called by muse, mutect2, varscan2
- OTOG | c.6495G>T p.P2165= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV61131999; called by muse, mutect2
- PROSER2 | c.1119C>T p.A373= | Silent (SNP) | VAF 4/67 reads (6%) | catalogued as rs1359916649; called by muse, mutect2
- SLC2A13 | c.1290A>T p.S430= | Silent (SNP) | VAF 12/272 reads (4%) | called by muse, mutect2
- SLC36A4 | c.1470T>A p.P490= | Silent (SNP) | VAF 22/429 reads (5%) | called by muse, mutect2
- SP100 | c.153C>T p.D51= | Silent (SNP) | VAF 10/266 reads (4%) | catalogued as COSV51003499; called by muse, mutect2
- ADH6 | c.-17C>G | 5'UTR (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- AGAP12P | n.1872G>T | RNA (SNP) | VAF 12/269 reads (4%) | called by muse, mutect2
- DPYS | c.950+24G>T | Intron (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2
- FHL2 | c.-75-15G>T | Intron (SNP) | VAF 14/136 reads (10%) | catalogued as rs571689781; called by muse, mutect2, varscan2
- GOLGA2 | c.-40G>C | 5'UTR (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- LAMB4 | c.-10T>A | 5'UTR (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- LNPEP | c.1946+28T>A | Intron (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- NAA40 | c.103-226G>T | Intron (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- SPATA31C1 | n.2845C>T | RNA (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- SSPOP | n.2290A>T | RNA (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- ZNF547 | c.*632G>A | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
